Surgical pathology report (de-identified scan), TCGA case TCGA-B1-A655, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B1-A655-01A (Primary Tumor).

AMENDED/CORRECTED REPORT:

Amended date:

Reason: Correct laterality designation of the partial nephrectomy

Paragraph of what changed: From right side to left side of Part 2 (diagnosis field). No other changes are made to the report

Communicated to by email on

Original sign-out date:

This Amended Report supersedes all prior reports under this accession number and should be the only one used for patient management. All reports, both original and amended, are maintained in electronic archives and are available upon request.

FINAL DIAGNOSIS:

Collection Date:

PART 1: FAT, OVERLYING TUMOR, RESECTION—

PORTION OF FIBROADIPOSE TISSUE AND ONE DETACHED SMALL FRAGMENT (0.1 CM) OF RENAL CELL CARCINOMA PRESENT (See Comment).

PART 2: LEFT KIDNEY, PARTIAL NEPHRECTOMY—

- A. RENAL CELL CARCINOMA WITH ONCOCYTIC FEATURES, FOAMY MACROPHAGES WITH FOCAL HEMOSIDERIN PIGMENT, AND IMMUNOREACTIVITY FOR ALPHA-METHYLACYL CoA RACEMASE; FAVOR RENAL CELL CARCINOMA, PAPILLARY TYPE 2 WITH A PREDOMINANTLY SOLID ARCHITECTURE.
- B. FUHRMAN NUCLEAR GRADE IS 3 OUT OF 4.
- C. NEOPLASM MEASURES 2.9 CM IN MAXIMUM DIMENSION.
- D. NEOPLASM APPEARS LIMITED TO THE KIDNEY WITH NO DEFINITIVE EXTRACAPSULAR EXTENSION IDENTIFIED.
- E. NEOPLASM IS PRESENT FOCALLY AT THE INKED CAPSULAR AND INKED PARENCHYMAL RESECTION MARGINS.
- F. NO LYMPHOVASCULAR INVASION IS IDENTIFIED.
- G. NON-NEOPLASTIC KIDNEY SHOWS CHRONIC CHANGES ASSOCIATED WITH PROXIMITY TO THE TUMOR.
- H. TNM PATHOLOGIC STAGE: pT1a Nx Mx (See Synoptic and Comment).

COMMENT:

Part 2: The renal mass consists of an oncocytic epithelial neoplasm with prominent foamy macrophages and hemosiderin laden macrophages associated with hemorrhage. The epithelial cells are arranged in solid, acinar, and focally papillary architectures. The neoplastic cells have large nuclei with prominent nucleoli and round nuclear contours. A limited panel of immunohistochemical stains is performed. The neoplastic cells are strongly immunoreactive for P504S (alpha-methylacyl CoA racemase) and are negative for cytokeratin 7 and carbonic anhydrase IX. Parvalbumin immunostain is equivocal, with a high background. The overall pathology favors a type 2 papillary renal cell carcinoma.

Parts 1 and 2: The renal cell carcinoma is focally present at the capsular resection margin in an area where the capsule is not intact (? capsular incision) and the parenchymal resection margin on the partial nephrectomy specimen. A microscopic detached fragment of carcinoma is present in the fat overlying the tumor (part 1). It is uncertain whether any microscopic residual carcinoma is present. Clinical / radiologic follow-up is recommended.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY KIDNEY TUMORS

SPECIMEN TYPE: Partial nephrectomy
LATERALITY: Left
TUMOR SITE: Upper pole
FOCALITY: Unifocal
TUMOR SIZE: Greatest dimension: 2.9 cm
Additional dimensions: 2.5 X 1.4 cm
MACROSCOPIC EXTENT OF TUMOR: Tumor limited to kidney
HISTOLOGIC TYPE: Other: Oncocytic renal cell carcinoma, favor type 2 papillary histologic type
HISTOLOGIC GRADE (Fuhrman Nuclear Grade): G3
PATHOLOGIC STAGING (pTNM): pT1a
pNX
Number of regional lymph nodes examined: 0
pMX
MARGINS: Margin(s) involved by invasive carcinoma
Renal capsular margin
Perinephric fat margin
Renal parenchymal margin
ADRENAL GLAND: Not present
LYMPH-VASCULAR INVASION (LVI): Absent/not identified

Source: NCI Genomic Data Commons file 15602ab6-089c-4831-bbd2-879c60ed6601 (TCGA-B1-A655.2240C6F0-5359-4A21-9275-B5D81F597168.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).